Surgical pathology report (de-identified scan), TCGA case TCGA-CS-4944, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-4944-01A (Primary Tumor).

[page 1 of 3]
ADDEDDED

TCGA-CS-4944

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. brain, Right temporal tumor (excision): astrocytoma, grade II of IV (WHO scale), see microscopic description, see comment
2. brain, Right temporal tumor (excision): astrocytoma, grade II of IV (WHO scale), see microscopic description, see comment

Comment:

Immunohistochemistry for the proliferation antigen Ki67 is pending and when completed, an addendum will be issued.

This diagnostic report has been personally interpreted by the signatory of record.

Addendum

Immunohistochemistry for the proliferation antigen Ki67 demonstrates less than 1% labeling of tumor cell nuclei.

The proliferation index is within the expected range for a grade II astrocytoma (WHO scale).

Microscopic Description:

The tumor consists of a diffusely infiltrative proliferation of moderately pleomorphic astrocytes. There is no endothelial proliferation or necrosis. No mitoses were identified. In some areas, particularly near the pial surface, there are clusters of Rosenthal fibers. However, there are no other histologic features to suggest a pilocytic astrocytoma.

[page 2 of 3]
[REDACTED]

Frozen Section Diagnosis:

1. Right temporal tumor: Glial neoplasm, no obvious high grade feature, [REDACTED]

Clinical History and Diagnosis:

Right temporal tumor

Source of Specimen:

- 1: Right temporal tumor
- 2: Right temporal tumor

Gross Description:

- [REDACTED]
1. Right temporal tumor: Received fresh for frozen section, labeled with the patient's name and "1. Right temporal tumor" is a 2.5 x 2.0 x 0.5 cm aggregate of pale to pink soft brain tissue. Touch preparations and frozen sections are prepared (50% of the specimen). The specimen is entirely submitted in 2 cassettes.

A frozen section control

B. remaining specimen

2. Right temporal tumor: Received in formalin, in a specimen container labeled with the patient's name and "#2 right temporal tumor", is a 4 x 2 x 1.5 cm aggregate of pal tan-pink soft brain tissue. The specimen is sectioned and entirely submitted in 4 cassettes.

Histology Laboratory

H&E

Part 2: Right temporal tumor

KI 67

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the [REDACTED] [REDACTED]

[page 3 of 3]
2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded.
Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded.
Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the Clinical Laboratory of [REDACTED]

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 82b888aa-f5e5-4d01-9e0c-f4cb0c900baf (TCGA-CS-4944.6845998B-B702-4F92-85BB-ED8405BF0051.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).